Somatic mutation profile of cancer-model specimen HCM-STAN-0846-C20-85A (3D Organoid, passage 6; aliquot HCM-STAN-0846-C20-85A-01D-A937-36), derived from the primary tumor of HCMI case HCM-STAN-0846-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 65.5 years (23,938 days).
Specimen HCM-STAN-0846-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e24df453-7cf2-49bc-9964-dafef22f5bfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0846-C20-11D (FFPE Scrolls), aliquot HCM-STAN-0846-C20-11D-04D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/520099f5-393b-4f58-943d-e1c9f7aad846

The open-access MAF lists 108 somatic variants for this specimen: 79 protein-altering or splice-affecting, 22 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 22, Nonsense Mutation 9, Intron 5, Frame Shift Del 3, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3944C>A p.S1315* | Nonsense Mutation (SNP) | VAF 175/404 reads (43%) | hotspot (GDC flag); catalogued as CM021066, CM106373, COSV57326747, COSV57328428, COSV57342242, COSV57397137; called by muse, mutect2, varscan2
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 180/365 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 162/322 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 340/341 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 119/221 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781186910, COSV56641970; called by muse, mutect2, varscan2
- ADAMTS6 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 125/282 reads (44%) | catalogued as COSV66865435; called by muse, mutect2, varscan2
- AGGF1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100462308; called by muse, mutect2, varscan2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 506/506 reads (100%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- ANK2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs747860838, COSV52158487; called by muse, mutect2, varscan2
- ARHGEF12 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1421729429; called by muse, mutect2, varscan2
- CACNA1B | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 50/636 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV53114810; called by muse, mutect2
- CAPN1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 247/489 reads (51%) | catalogued as rs751243573, COSV54201789; called by muse, varscan2
- CCDC42 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 388/388 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs149912256; called by muse, mutect2, varscan2
- CDK8 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1418353379, COSV67422530; called by muse, mutect2, varscan2
- EXT1 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 109/268 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs762790189, COSV100983906; called by muse, mutect2, varscan2
- FAM170B | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 231/468 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374774215, COSV61254342; called by muse, mutect2, varscan2
- FOXD4 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 250/551 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1390586065; called by muse, mutect2, varscan2
- GAL3ST3 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 135/243 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV100360678; called by muse, mutect2, varscan2
- HSD11B1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 208/415 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs554862870, COSV54825694; called by muse, mutect2, varscan2
- KCNH2 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 55/598 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs539146547; ClinVar: uncertain significance; called by muse, mutect2
- KCNMA1 | c.3557G>A p.R1186Q (on ENST00000286628 / NM_001161352.2; = p.R1128Q on NM_002247.4) | Missense Mutation (SNP) | VAF 172/392 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs200141207; ClinVar: uncertain significance; called by muse, varscan2
- KDM4B | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 166/328 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs781760371, COSV50215768; called by muse, mutect2, varscan2
- MAPK15 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 302/665 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554620196; called by muse, mutect2, varscan2
- NLGN4X | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 166/349 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323708; called by muse, mutect2, varscan2
- NMNAT3 | c.206G>A p.R69Q (on ENST00000296202 / NM_001320512.1; = p.R32Q on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/569 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs889792534; called by muse, mutect2
- NUGGC | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 195/427 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs377099582; called by muse, mutect2, varscan2
- OR5D16 | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as rs577805845; called by muse, mutect2, varscan2
- POLE | c.5851G>A p.E1951K | Missense Mutation (SNP) | VAF 124/439 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs768917089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSRC1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV64020973; called by muse, mutect2, varscan2
- RAMP1 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 214/468 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs147692476, COSV54537412; called by muse, varscan2
- RHPN1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 225/462 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1363547627; called by muse, mutect2, varscan2
- SHISA9 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs760672521, COSV69631527; called by muse, mutect2, varscan2
- SORL1 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 198/390 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM166733; called by muse, mutect2, varscan2
- TANC2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 108/268 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1437062053; called by muse, varscan2
- TNS3 | c.2612del p.P871Rfs*2 | Frame Shift Del (DEL) | VAF 183/391 reads (47%) | catalogued as COSV60792884; called by mutect2, varscan2
- TRH | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 212/400 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs149654673; called by muse, mutect2, varscan2
- AC005697.1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 125/265 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- AKAP11 | c.4261G>C p.A1421P | Missense Mutation (SNP) | VAF 168/311 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- APC | c.4366_4369del p.K1456Hfs*16 | Frame Shift Del (DEL) | VAF 140/325 reads (43%) | called by mutect2, varscan2
- ATP5F1B | c.1381C>G p.Q461E | Missense Mutation (SNP) | VAF 187/415 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CATSPER3 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- CCR3 | c.561C>A p.Y187* | Nonsense Mutation (SNP) | VAF 143/342 reads (42%) | called by muse, mutect2, varscan2
- CHD6 | c.5674C>A p.H1892N | Missense Mutation (SNP) | VAF 186/766 reads (24%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST3 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 96/474 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBG2 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCAF12L1 | c.794T>G p.V265G | Missense Mutation (SNP) | VAF 277/599 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHA5 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 174/349 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- FXYD2 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 194/398 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- HSF4 | c.1064C>T p.P355L (on ENST00000521374 / NM_001040667.3; = p.P325L on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/252 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IZUMO1 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- JAK1 | c.2821A>T p.K941* | Nonsense Mutation (SNP) | VAF 148/148 reads (100%) | called by muse, mutect2, varscan2
- KCNQ3 | c.506C>G p.A169G | Missense Mutation (SNP) | VAF 125/280 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LMNB2 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 246/506 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LYST | c.6973G>T p.D2325Y | Missense Mutation (SNP) | VAF 198/198 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- MAGEL2 | c.3154C>T p.R1052* | Nonsense Mutation (SNP) | VAF 148/325 reads (46%) | called by muse, varscan2
- MCM7 | c.544T>G p.Y182D | Missense Mutation (SNP) | VAF 152/300 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NCAM1 | c.1398C>A p.Y466* (on ENST00000316851 / NM_181351.5; = p.Y456* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 123/280 reads (44%) | called by muse, mutect2, varscan2
- NHLH1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 271/547 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, varscan2
- NPHP1 | c.1931A>G p.D644G (on ENST00000393272 / NM_207181.4; = p.D645G on NM_000272.5) | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIKFYVE | c.2536G>C p.D846H | Missense Mutation (SNP) | VAF 161/341 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PRKDC | c.12383T>A p.M4128K | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RNF39 | c.599T>G p.V200G | Missense Mutation (SNP) | VAF 136/349 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2
- RP1 | c.5226del p.D1742Efs*7 | Frame Shift Del (DEL) | VAF 113/243 reads (47%) | called by mutect2, varscan2
- SLC17A6 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 128/300 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SLC34A2 | c.1622C>A p.P541Q | Missense Mutation (SNP) | VAF 254/500 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC44A1 | c.280_281insG p.F94Cfs*15 | Frame Shift Ins (INS) | VAF 116/234 reads (50%) | called by mutect2, varscan2
- SPATA3 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 179/366 reads (49%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- SPATA31D1 | c.4153G>T p.V1385L | Missense Mutation (SNP) | VAF 149/375 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- STRA6 | c.1164C>G p.H388Q | Missense Mutation (SNP) | VAF 147/287 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TEX13C | c.2032C>A p.P678T | Missense Mutation (SNP) | VAF 257/577 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.2033C>A p.P678H | Missense Mutation (SNP) | VAF 254/575 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPD52L1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 131/254 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VIRMA | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 175/381 reads (46%) | called by muse, mutect2, varscan2
- ZNF304 | c.1836A>C p.E612D | Missense Mutation (SNP) | VAF 213/429 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF365 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 190/426 reads (45%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.009); called by muse, varscan2
- ZNF366 | c.1543A>T p.N515Y | Missense Mutation (SNP) | VAF 168/320 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF577 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 107/221 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ZNF717 | c.1163C>A p.T388N | Missense Mutation (SNP) | VAF 175/482 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ACP7 | c.234C>T p.F78= | Silent (SNP) | VAF 196/437 reads (45%) | called by muse, mutect2, varscan2
- ADCY8 | c.2554C>A p.R852= | Silent (SNP) | VAF 200/429 reads (47%) | catalogued as COSV53901980; called by muse, mutect2, varscan2
- AHNAK2 | c.10518C>T p.D3506= | Silent (SNP) | VAF 570/584 reads (98%) | catalogued as rs199879973; called by muse, varscan2
- CCDC168 | c.8496C>A p.I2832= | Silent (SNP) | VAF 441/671 reads (66%) | called by muse, mutect2, varscan2
- CECR2 | c.3351C>T p.N1117= (on ENST00000342247 / NM_001290047.2; = p.N933= on NM_001290046.1) | Silent (SNP) | VAF 82/367 reads (22%) | catalogued as rs763292892, COSV52844976; called by muse, mutect2, varscan2
- ELOA | c.60G>A p.E20= | Silent (SNP) | VAF 246/249 reads (99%) | called by muse, mutect2, varscan2
- ENAM | c.3264G>A p.T1088= | Silent (SNP) | VAF 189/375 reads (50%) | catalogued as rs751620386; called by muse, mutect2, varscan2
- FOXN1 | c.492C>T p.D164= | Silent (SNP) | VAF 225/485 reads (46%) | catalogued as rs139818870; called by muse, mutect2, varscan2
- GPR139 | c.801C>T p.S267= | Silent (SNP) | VAF 195/432 reads (45%) | catalogued as rs764200611; called by muse, mutect2, varscan2
- INPP5A | c.417C>T p.T139= | Silent (SNP) | VAF 142/332 reads (43%) | catalogued as rs376694651; called by muse, varscan2
- IRF2BPL | c.1326T>C p.Y442= | Silent (SNP) | VAF 415/415 reads (100%) | called by muse, mutect2, varscan2
- LAMA2 | c.1113G>A p.K371= | Silent (SNP) | VAF 160/353 reads (45%) | called by muse, mutect2, varscan2
- LORICRIN | c.750C>T p.S250= | Silent (SNP) | VAF 281/588 reads (48%) | catalogued as rs747527092; called by muse, varscan2
- MTCH1 | c.336G>A p.P112= | Silent (SNP) | VAF 142/312 reads (46%) | catalogued as rs755488075, COSV65320040; called by muse, varscan2
- MTMR14 | c.1680G>A p.T560= | Silent (SNP) | VAF 224/462 reads (48%) | catalogued as rs1323982567, COSV56007207; called by muse, varscan2
- PAPOLA | c.1161C>G p.R387= | Silent (SNP) | VAF 99/218 reads (45%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1116A>G p.P372= | Silent (SNP) | VAF 162/363 reads (45%) | catalogued as COSV50649910; called by muse, mutect2, varscan2
- PCDHGA1 | c.1674C>T p.N558= | Silent (SNP) | VAF 229/463 reads (49%) | catalogued as COSV65295434, COSV65296327; called by muse, mutect2, varscan2
- POTEI | c.378C>T p.S126= | Silent (SNP) | VAF 158/385 reads (41%) | catalogued as rs537865534; called by muse, mutect2, varscan2
- UNC80 | c.504C>T p.D168= | Silent (SNP) | VAF 188/390 reads (48%) | catalogued as rs759046455, COSV55906348; called by muse, varscan2
- VWA3A | c.1950C>T p.G650= | Silent (SNP) | VAF 274/536 reads (51%) | catalogued as rs377509870; called by muse, mutect2
- ZNF135 | c.483G>A p.Q161= (on ENST00000313434 / NM_001289401.2; = p.Q173= on NM_003436.4) | Silent (SNP) | VAF 168/362 reads (46%) | catalogued as COSV57884766; called by muse, mutect2, varscan2
- AC011503.1 | n.467+8666G>T | Intron (SNP) | VAF 126/265 reads (48%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*187A>T | 3'UTR (SNP) | VAF 255/527 reads (48%) | called by muse, mutect2, varscan2
- ATRIP | c.*990G>A | 3'UTR (SNP) | VAF 169/363 reads (47%) | catalogued as rs1388292235; called by muse, mutect2, varscan2
- CXCL12 | c.266+779G>A | Intron (SNP) | VAF 214/485 reads (44%) | catalogued as rs754639751, COSV100638867; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-28390T>C | Intron (SNP) | VAF 148/257 reads (58%) | called by muse, mutect2, varscan2
- STEAP1B | c.706-18845C>T | Intron (SNP) | VAF 71/422 reads (17%) | catalogued as rs1286141950; called by muse, mutect2, varscan2
- TTC39A | c.999+169C>A | Intron (SNP) | VAF 194/197 reads (98%) | catalogued as rs746408253; called by muse, mutect2
